Somatic mutation profile of tumor specimen TCGA-BR-8368-01A (aliquot TCGA-BR-8368-01A-11D-2340-08) from TCGA case TCGA-BR-8368, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 84.5 years (30,874 days).
Specimen TCGA-BR-8368-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6bfd2ce-25ed-49d8-adb5-c43a7ea1c624.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8368-10A (Blood Derived Normal), aliquot TCGA-BR-8368-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/345cb2c4-3018-48b2-871d-1f473a3672b4

The open-access MAF lists 1,173 somatic variants for this specimen: 878 protein-altering or splice-affecting, 270 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 543, Silent 270, Frame Shift Del 216, Nonsense Mutation 42, Frame Shift Ins 38, In Frame Del 16, Splice Site 14, Intron 11, Splice Region 7, RNA 5, 3'UTR 5, 3'Flank 2.

Variants (750 of 1,173; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs398123131, CM031626, COSV61689980; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATM | c.5712del p.K1904Nfs*13 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs587781730; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.1813del p.I605Yfs*9 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs80359306; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CHST3 | c.533del p.G178Afs*38 | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | catalogued as rs769540174; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 33/89 reads (37%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MSH3 | c.1148dup p.N385Qfs*19 | Frame Shift Ins (INS) | VAF 57/166 reads (34%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 22/50 reads (44%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- OPLAH | c.2608dup p.H870Pfs*92 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMARCB1 | c.992G>A p.R331H (on ENST00000263121; = p.R377H on NM_003073.5) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs387906812, CM122478, COSV51954090, COSV51954233, COSV51954740; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TTN | c.58678C>T p.R19560* (on ENST00000591111; = p.R12136* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as rs764243269, CM121826, COSV100622067, COSV60174862; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1705C>T p.R569* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as rs747434741, COSV55748340; called by muse, mutect2, varscan2
- ABCA3 | c.3902C>T p.P1301L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as rs762699052, CM057309, COSV57056321; called by muse, mutect2, varscan2
- ABCA5 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as rs756547724, COSV67017543; called by muse, mutect2, varscan2
- ABCB10 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1482714067, COSV60622287; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 33/81 reads (41%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCG1 | c.1046G>A p.C349Y | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as rs756353022, COSV59207141; called by muse, mutect2, varscan2
- ABHD8 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV53112706; called by muse, mutect2, varscan2
- AC068580.4 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.965); catalogued as COSV52589051; called by muse, mutect2, varscan2
- AC136428.1 | c.105del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | catalogued as rs763538641; called by mutect2, varscan2
- ACACB | c.2628-1G>A p.X876_splice | Splice Site (SNP) | VAF 14/80 reads (18%) | catalogued as COSV58139457; called by muse, mutect2, varscan2
- ACBD3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV64729752; called by muse, mutect2, varscan2
- ACO2 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.344); catalogued as rs752600434, COSV53441520; called by muse, mutect2, varscan2
- ACSL3 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756484315, COSV62483431; called by muse, mutect2, varscan2
- ACTR5 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs779564620, COSV54761496, COSV99710065; called by muse, varscan2
- ADAD1 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.367); catalogued as COSV56645143; called by muse, mutect2, varscan2
- ADAM12 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64110036; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS5 | c.1356G>A p.W452* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV53181108; called by muse, mutect2, varscan2
- ADGRB1 | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs751615897, COSV60099907; called by muse, mutect2, varscan2
- ADGRB3 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.056); catalogued as rs112866971, COSV65404904; called by muse, mutect2, varscan2
- ADGRG4 | c.4145G>T p.S1382I | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV54961326; called by muse, mutect2, varscan2
- ADGRG5 | c.601T>C p.W201R | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV61083884; called by muse, mutect2, varscan2
- AGAP4 | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1349979816, COSV101432636; called by mutect2, varscan2
- AGFG2 | c.1386G>T p.M462I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV53546055; called by muse, mutect2, varscan2
- AGL | c.1423+2T>C p.X475_splice | Splice Site (SNP) | VAF 37/105 reads (35%) | catalogued as COSV54055291; called by muse, mutect2, varscan2
- AGO3 | c.881+1G>A p.X294_splice | Splice Site (SNP) | VAF 33/107 reads (31%) | catalogued as COSV55793476; called by muse, mutect2, varscan2
- AHNAK | c.10006G>A p.V3336I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs772113273, COSV57221087; called by muse, mutect2, varscan2
- AKAP11 | c.2026T>G p.C676G | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV50298506; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as COSV62339755; called by mutect2, varscan2
- AMIGO2 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as rs1357916393, COSV56974838; called by muse, mutect2, varscan2
- AMMECR1 | c.520G>T p.G174* | Nonsense Mutation (SNP) | VAF 60/180 reads (33%) | catalogued as COSV53318925; called by muse, mutect2, varscan2
- AMOTL2 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51439927; called by muse, mutect2, varscan2
- AMPH | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.315); catalogued as COSV57748704; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 26/124 reads (21%) | catalogued as rs34047276; called by mutect2, varscan2
- ANK1 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs764141047, COSV55886773; called by muse, mutect2, varscan2
- ANKRD11 | c.1989C>G p.D663E | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs773130868, COSV56365326; called by muse, mutect2, varscan2
- AP2A1 | c.1013T>C p.L338P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62819546; called by muse, mutect2, varscan2
- AP3D1 | c.2990G>A p.G997D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV61430435; called by muse, mutect2, varscan2
- APBB3 | c.1310G>T p.R437L (on ENST00000357560 / NM_133173.2; = p.R444L on NM_006051.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.552); catalogued as COSV100296470, COSV60365824; called by muse, mutect2, varscan2
- ARAF | c.619del p.L207Yfs*85 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as COSV51695741; called by mutect2, pindel, varscan2
- ARHGAP21 | c.4918G>A p.E1640K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs758648434, COSV57608519; called by muse, mutect2, varscan2
- ARHGAP33 | c.1826T>C p.L609P | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); catalogued as rs111354763, COSV50132882; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 51/83 reads (61%) | catalogued as rs781483073; called by mutect2, pindel, varscan2
- ARHGEF17 | c.1850dup p.G618Wfs*4 | Frame Shift Ins (INS) | VAF 13/59 reads (22%) | catalogued as rs761146124; called by mutect2, varscan2
- ARHGEF17 | c.4810C>T p.P1604S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55234601; called by muse, mutect2, varscan2
- ARHGEF3 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs768543223, COSV56323655, COSV56327209; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as rs776520069; called by mutect2, varscan2
- ARMT1 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs1348351602, COSV66178799; called by muse, mutect2, varscan2
- ARVCF | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.455); catalogued as rs772484913, COSV54268209; called by muse, mutect2, varscan2
- ASB1 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs781739770, COSV52827589; called by muse, mutect2, varscan2
- ASH1L | c.3962G>A p.R1321Q | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs1358026443, COSV64205657; called by muse, mutect2, varscan2
- ATG2A | c.333A>G p.P111= | Splice Region (SNP) | VAF 5/9 reads (56%) | catalogued as COSV65967546; called by muse, mutect2, varscan2
- ATG4A | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756276852, COSV58966491; called by muse, mutect2, varscan2
- ATG7 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61614076; called by muse, mutect2, varscan2
- ATRX | c.1037T>C p.L346P | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64879672; called by muse, mutect2
- B3GAT2 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.989); catalogued as rs781519334, COSV57641974; called by muse, varscan2
- B3GNT3 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1286270349, COSV59438298; called by muse, mutect2, varscan2
- B4GALNT4 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57324446; called by muse, mutect2, varscan2
- BAG3 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs200479768, COSV64842263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCLAF1 | c.1388A>G p.E463G | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs765613005, COSV62143874; called by muse, mutect2, varscan2
- BCLAF1 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs142177067; called by muse, mutect2, varscan2
- BICD1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1223369923, COSV55682750; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs755506199; called by mutect2, varscan2
- BIRC7 | c.875G>C p.R292P (on ENST00000217169 / NM_139317.3; = p.R274P on NM_022161.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.233); catalogued as COSV53901965; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | catalogued as COSV56263190; called by mutect2, varscan2
- BRCC3 | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); catalogued as COSV57462624, COSV57463109, COSV57463187; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 34/81 reads (42%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BRWD1 | c.5446dup p.T1816Nfs*6 | Frame Shift Ins (INS) | VAF 58/125 reads (46%) | catalogued as rs1568856013; called by mutect2, varscan2
- BTAF1 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56429518; called by muse, mutect2, varscan2
- BUB1B | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs377612791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs751388819; called by mutect2, varscan2
- C1QL2 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55607058; called by mutect2, varscan2
- C1QTNF5 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.73); catalogued as COSV60990081; called by muse, mutect2, varscan2
- C1orf141 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as COSV63992973; called by muse, mutect2, varscan2
- C21orf62 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377322005; called by muse, mutect2, varscan2
- C2CD3 | c.5335C>T p.R1779C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as rs752547363, COSV58095516; called by muse, mutect2
- C2orf66 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61099001; called by muse, mutect2, varscan2
- C3orf20 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs764690622, COSV53784823; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 45/209 reads (22%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CACNA1C | c.6224del p.G2075Afs*38 (on ENST00000399634 / NM_001167625.1; = p.G2004Afs*38 on NM_000719.7) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as COSV59754641; called by mutect2, pindel, varscan2
- CACNA1E | c.5078G>A p.R1693H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs964315512, COSV62404935; called by muse, mutect2, varscan2
- CACNA1F | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs782053409, COSV59905309; called by muse, mutect2, varscan2
- CACNA2D1 | c.2273C>T p.T758I (on ENST00000356253 / NM_001366867.1; = p.T746I on NM_000722.4) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as rs779277828, COSV62384801; called by muse, mutect2, varscan2
- CADM1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.07); catalogued as COSV59015984; called by muse, mutect2, varscan2
- CARD14 | c.2029del p.D677Tfs*45 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs758713305, COSV60125198; called by mutect2, pindel, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | catalogued as rs770159446; called by mutect2, varscan2
- CATIP | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs776271441, COSV56823479; called by muse, mutect2, varscan2
- CATSPER4 | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58793819; called by muse, mutect2, varscan2
- CAVIN3 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58269339; called by muse, mutect2, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1268177561; called by mutect2, pindel
- CCDC171 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.954); catalogued as COSV52646344; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 50/120 reads (42%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC6 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1242284607, COSV54058044; called by muse, varscan2
- CCER1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386474051, COSV62647391; called by muse, mutect2, varscan2
- CCN4 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs529938783, COSV51533599; called by muse, mutect2, varscan2
- CCN4 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as rs764654100, COSV51533628; called by muse, mutect2, varscan2
- CCR10 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV52852209; called by muse, mutect2
- CD4 | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV50592625; called by muse, mutect2, varscan2
- CD5L | c.392T>C p.F131S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV63822505; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC16 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52960591; called by muse, mutect2, varscan2
- CDCA4 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs762874162, COSV60315280; called by muse, mutect2, varscan2
- CDH16 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1490162866, COSV55335435; called by muse, mutect2, varscan2
- CDH6 | c.597C>A p.Y199* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV54073851; called by muse, mutect2, varscan2
- CDK20 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs773980056, COSV57483306; called by muse, mutect2, varscan2
- CELSR2 | c.4333G>A p.G1445R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs753290065, COSV54775550; called by muse, mutect2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 33/80 reads (41%) | catalogued as rs751492244; called by mutect2, varscan2
- CFDP1 | c.157del p.R53Efs*18 | Frame Shift Del (DEL) | VAF 37/135 reads (27%) | catalogued as rs1296337835; called by mutect2, pindel, varscan2
- CHST7 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV52100545; called by muse, mutect2, varscan2
- CLASP2 | c.2008A>G p.M670V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs773840527, COSV56287102; called by muse, mutect2, varscan2
- CLCC1 | c.1149G>T p.E383D (on ENST00000356970 / NM_001377464.1; = p.E333D on NM_015127.5) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV56764558; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 36/54 reads (67%) | catalogued as rs763852712; called by mutect2, pindel, varscan2
- CLEC11A | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV51574487; called by muse, mutect2, varscan2
- CLK2 | c.1441C>T p.R481C (on ENST00000368361 / NM_001294339.2; = p.R480C on NM_003993.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs771821636, COSV100226611, COSV56946355; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 43/125 reads (34%) | catalogued as rs369752219; called by mutect2, varscan2
- CLOCK | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs1317731193, COSV59403476; called by muse, mutect2, varscan2
- CNGA3 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs77733216, COSV55625289; called by muse, mutect2, varscan2
- CNN1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs748000390, COSV52947589; called by muse, mutect2, varscan2
- CNST | c.323T>A p.I108N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.157); catalogued as rs757771014, COSV63620327; called by muse, mutect2, varscan2
- CNTLN | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV52086170; called by muse, varscan2
- CNTN6 | c.1427C>A p.S476* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV63163128, COSV63179673; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs374805044; called by mutect2, varscan2
- COL11A2 | c.4705C>T p.R1569C (on ENST00000341947 / NM_080680.3; = p.R1462C on NM_080679.2) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs727504458, COSV59497007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL2A1 | c.1779G>T p.Q593H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); catalogued as COSV61532207; called by muse, mutect2, varscan2
- COL5A2 | c.645+2T>C p.X215_splice | Splice Site (SNP) | VAF 31/61 reads (51%) | catalogued as COSV66411557; called by muse, mutect2, varscan2
- COL6A2 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs372936386; called by muse, mutect2, varscan2
- COLEC11 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52595240; called by muse, mutect2, varscan2
- COP1 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as COSV58170961; called by muse, mutect2, varscan2
- COPB1 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs145451352; called by muse, mutect2, varscan2
- COPB2 | c.2362C>A p.L788I | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.13); catalogued as COSV60350663; called by muse, mutect2, varscan2
- COPB2 | c.1186T>C p.W396R | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60813161; called by muse, mutect2, varscan2
- CPEB2 | c.2897A>G p.E966G | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV52593308; called by muse, varscan2
- CPNE1 | c.974G>A p.S325N (on ENST00000352393; = p.S330N on NM_003915.5) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV58293102; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CREBBP | c.4948G>A p.V1650I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs776549587, COSV52131586; called by muse, mutect2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CRX | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs559181643, COSV55759295; called by muse, mutect2, varscan2
- CRYBG3 | c.7558C>T p.R2520C | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369729142; called by muse, mutect2, varscan2
- CSNK1G1 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777544, CM145529, COSV57311625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSPG4 | c.2716C>A p.L906I | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV57898272; called by muse, mutect2, varscan2
- CSPG4 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs144233988; called by muse, mutect2, varscan2
- CUL1 | c.1574T>C p.L525S | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV57390252; called by muse, mutect2, varscan2
- CUL1 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57390264; called by muse, mutect2, varscan2
- CUL9 | c.7012G>T p.G2338* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV52731122; called by muse, mutect2, varscan2
- CUX2 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55639101; called by muse, mutect2, varscan2
- CYB561 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs774891899, COSV62539990; called by mutect2, varscan2
- CYP2A13 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs780550795, COSV57838874; called by muse, mutect2, varscan2
- CYP2F1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs369493486, COSV58528186; called by muse, mutect2, varscan2
- CYP4F8 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs766290409, COSV57854021; called by muse, mutect2, varscan2
- DAXX | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56471099; called by muse, mutect2, varscan2
- DAZAP1 | c.952del p.A318Qfs*17 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | catalogued as COSV51833566; called by mutect2, pindel, varscan2
- DDAH1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV52305342; called by muse, mutect2, varscan2
- DDHD2 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763476356, COSV68157058; called by muse, mutect2, varscan2
- DDN | c.1130_1132del p.G377del | In Frame Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs759771691; called by mutect2, pindel, varscan2
- DDX28 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV60105899; called by muse, mutect2, varscan2
- DEAF1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.267); catalogued as rs866708744, COSV58608084; called by muse, varscan2
- DEFB126 | c.59-2A>G p.X20_splice | Splice Site (SNP) | VAF 14/49 reads (29%) | catalogued as rs960983335, COSV66694923; called by muse, mutect2, varscan2
- DENND5B | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs372657171; called by muse, mutect2, varscan2
- DGAT1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139792712; called by muse, mutect2, varscan2
- DGCR8 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV100708044, COSV61225549; called by muse, mutect2, varscan2
- DGKD | c.1348G>A p.A450T (on ENST00000264057 / NM_152879.3; = p.A406T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51039841, COSV51066096; called by muse, mutect2
- DHRSX | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV58135919; called by muse, varscan2
- DHX33 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs770385496, COSV56579895; called by muse, varscan2
- DISP3 | c.3688G>A p.G1230S | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs374923562, COSV53824728; called by muse, mutect2, varscan2
- DLG1 | c.1720G>T p.G574C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58386673; called by muse, mutect2, varscan2
- DLGAP4 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs753922102, COSV59420226; called by muse, mutect2, varscan2
- DMTN | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177031213, COSV56113404; called by muse, mutect2, varscan2
- DMXL1 | c.6496T>C p.S2166P | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60716154; called by muse, mutect2, varscan2
- DNAH1 | c.7210del p.H2404Tfs*37 | Frame Shift Del (DEL) | VAF 27/141 reads (19%) | catalogued as COSV70226426, COSV70233203; called by mutect2, pindel, varscan2
- DNAH7 | c.3221del p.L1074Cfs*23 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAJC13 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV53454021; called by muse, mutect2, varscan2
- DNAJC13 | c.3625C>T p.R1209C | Missense Mutation (SNP) | VAF 113/321 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758884693, COSV53451748; called by muse, mutect2, varscan2
- DNAJC8 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 55/174 reads (32%) | catalogued as rs1434155053, COSV99746191; called by muse, varscan2
- DNM2 | c.2377dup p.L793Pfs*31 (on ENST00000355667 / NM_001005360.3; = p.L789Pfs*31 on NM_004945.3) | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | catalogued as rs764391392, COSV53034926; called by mutect2, varscan2
- DOCK1 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs373968953; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | catalogued as rs748134881; called by mutect2, varscan2
- DOHH | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); catalogued as COSV51745400; called by muse, mutect2, varscan2
- DPP7 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs745368679, COSV65371561; called by muse, mutect2, varscan2
- DPPA2 | c.371G>T p.R124M | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV72118188; called by muse, mutect2, varscan2
- DPYS | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs957809439, COSV60910943; called by muse, mutect2, varscan2
- DUOX2 | c.3260C>T p.A1087V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs776772769, COSV66533103; called by muse, mutect2, varscan2
- DUSP16 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as COSV53808629; called by muse, mutect2, varscan2
- ECEL1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs146580059; called by muse, mutect2, varscan2
- EEPD1 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as rs752270387, COSV54200830; called by muse, mutect2, varscan2
- ELAPOR2 | c.2860C>T p.Q954* (on ENST00000450689 / NM_001142749.3; = p.Q787* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV51888771; called by muse, mutect2, varscan2
- ELAVL1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV60967483; called by muse, mutect2, varscan2
- ELMO3 | c.1879C>T p.Q627* (on ENST00000652269; = p.Q574* on NM_024712.5) | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs1370661101, COSV58527691; called by muse, mutect2, varscan2
- ENTPD3 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57195369; called by muse, mutect2, varscan2
- EPB41L3 | c.3237G>T p.E1079D | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV59448726, COSV59449179; called by muse, mutect2, varscan2
- EPB41L3 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1050259718, COSV59445208, COSV59460193; called by muse, mutect2, varscan2
- EPS8L1 | c.1303G>A p.A435T (on ENST00000201647 / NM_133180.3; = p.A308T on NM_017729.3) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs771291960, COSV52383993; called by muse, mutect2, varscan2
- ESR1 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52795950; called by muse, mutect2, varscan2
- ESYT1 | c.2680T>C p.W894R | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.234); catalogued as COSV57274716; called by muse, mutect2, varscan2
- FABP9 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV66911677; called by muse, mutect2, varscan2
- FAM167A | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1333723238, COSV52704392; called by muse, mutect2, varscan2
- FAM47A | c.1929G>T p.K643N | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as COSV60498246; called by muse, varscan2
- FAM83F | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs778728277, COSV61000650; called by muse, mutect2, varscan2
- FAM91A1 | c.1696-2A>G p.X566_splice | Splice Site (SNP) | VAF 71/216 reads (33%) | catalogued as COSV58238221; called by muse, mutect2, varscan2
- FASTKD1 | c.10dup p.T4Nfs*34 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | catalogued as rs771228336; called by mutect2, varscan2
- FASTKD2 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186489901; called by muse, mutect2, varscan2
- FAT4 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67892588; called by muse, varscan2
- FBLN2 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs772029530, COSV55487740, COSV55490924; called by muse, mutect2, varscan2
- FBN3 | c.1610C>T p.T537I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV54455536; called by muse, mutect2, varscan2
- FBXL2 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV52140477; called by muse, mutect2, varscan2
- FCGBP | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs1217493425; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FERMT1 | c.1139+1G>C p.X380_splice | Splice Site (SNP) | VAF 27/83 reads (33%) | catalogued as COSV54094998; called by muse, mutect2, varscan2
- FGD3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747350454, COSV61598631, COSV61600228; called by muse, mutect2, varscan2
- FGF7 | c.535del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs777372807; called by mutect2, varscan2
- FGFR1OP2 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.106); catalogued as COSV57587648; called by muse, mutect2, varscan2
- FLNA | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs782067087, COSV61039883; called by muse, mutect2, varscan2
- FLNA | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.028); catalogued as rs782034946, COSV61046979; called by muse, mutect2, varscan2
- FLNB | c.6860C>T p.A2287V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55885809; called by muse, mutect2, varscan2
- FLNC | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554396387, COSV57950774, COSV57959538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNIP2 | c.688G>T p.G230* | Nonsense Mutation (SNP) | VAF 59/194 reads (30%) | catalogued as COSV52442298; called by muse, mutect2, varscan2
- FOXD4L5 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs781582393, COSV101073104, COSV66241318; called by muse, mutect2, varscan2
- FRK | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750533470, COSV73384098; called by muse, mutect2, varscan2
- FRMD1 | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs771877804, COSV51963407; called by muse, mutect2, varscan2
- FUBP1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs556028059, COSV53934225; called by muse, mutect2, varscan2
- FZD3 | c.888dup p.T297Yfs*25 | Frame Shift Ins (INS) | VAF 38/150 reads (25%) | catalogued as rs765036679; called by mutect2, varscan2
- FZD4 | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV72294550; called by muse, mutect2, varscan2
- G3BP1 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1264044374, COSV62366457; called by muse, mutect2, varscan2
- GABRB1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54970002; called by muse, mutect2, varscan2
- GABRR1 | c.695del p.K232Rfs*6 | Frame Shift Del (DEL) | VAF 48/141 reads (34%) | catalogued as COSV65619657; called by mutect2, pindel, varscan2
- GALNT1 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV52453511; called by muse, mutect2
- GALNT16 | c.*1C>T | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as rs1012727233, COSV100545869; called by muse, mutect2
- GATA3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs774889150, CM043919, COSV60520494; called by muse, mutect2, varscan2
- GFAP | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs770249831, COSV53648526; called by muse, mutect2, varscan2
- GFPT1 | c.754G>A p.G252R (on ENST00000357308 / NM_001244710.2; = p.G234R on NM_002056.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61949097; called by muse, mutect2, varscan2
- GLCE | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs552257481, COSV55944119; called by muse, mutect2, varscan2
- GLI2 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as rs370333257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLUL | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 119/312 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs1288022473, COSV59382536; called by muse, mutect2, varscan2
- GNA14 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770804772, COSV59026116; called by muse, mutect2, varscan2
- GOLGA2 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as rs761852586, COSV57853527; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 38/145 reads (26%) | catalogued as rs370114090; called by mutect2, varscan2
- GPC5 | c.1393G>C p.V465L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV65611401; called by muse, mutect2, varscan2
- GPR101 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs942531177, COSV53239550; called by muse, mutect2, varscan2
- GPR158 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV66275933; called by muse, mutect2, varscan2
- GPR27 | c.151C>A p.R51S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV55205675; called by muse, mutect2, varscan2
- GPR37L1 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV66162554; called by muse, mutect2, varscan2
- GPR6 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.163); catalogued as COSV51572713, COSV99254541; called by muse, mutect2
- GPS1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1434721433, COSV57649745; called by muse, mutect2, varscan2
- GPS1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs375649658, COSV57651450; called by muse, mutect2, varscan2
- GPX3 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV66313065; called by muse, mutect2, varscan2
- GRIA3 | c.1291C>T p.L431= | Splice Region (SNP) | VAF 44/142 reads (31%) | catalogued as COSV52070328; called by muse, mutect2, varscan2
- GRIN2D | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs1246986089, COSV54380575; called by muse, mutect2, varscan2
- GRM6 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs760164627, COSV51436761; called by muse, mutect2, varscan2
- GRPR | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1351631731, COSV66669848; called by muse, mutect2, varscan2
- GSN | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57999127; called by muse, mutect2
- GSN | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); catalogued as rs371328761; called by muse, mutect2, varscan2
- GTF2E2 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV63478720, COSV63479152; called by muse, mutect2, varscan2
- GTF3C4 | c.1691del p.K564Rfs*18 | Frame Shift Del (DEL) | VAF 53/165 reads (32%) | catalogued as rs1241168444, COSV64645321; called by mutect2, pindel, varscan2
- GUCY1A2 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56478639; called by muse, mutect2, varscan2
- GUCY2F | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV54298014; called by muse, mutect2, varscan2
- GZF1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs780925612, COSV57637434; called by mutect2, varscan2
- GZF1 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs891711571, COSV100582482; called by muse, mutect2
- HACD3 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs756832499, COSV56011987; called by muse, mutect2
- HDAC11 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs372456898; called by muse, mutect2, varscan2
- HDLBP | c.3376C>T p.Q1126* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV60498541; called by muse, mutect2, varscan2
- HECA | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1002814746, COSV62768233; called by muse, mutect2, varscan2
- HECTD1 | c.7367C>T p.T2456M | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs750708787, COSV67947639; called by muse, mutect2, varscan2
- HECTD1 | c.2703G>T p.K901N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV65991294; called by muse, mutect2, varscan2
- HEPACAM2 | c.554del p.N185Mfs*25 (on ENST00000394468 / NM_001039372.4; = p.N173Mfs*25 on NM_198151.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/105 reads (33%) | catalogued as COSV59062549; called by mutect2, pindel, varscan2
- HEPH | c.3393G>A p.W1131* (on ENST00000343002; = p.W864* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV57967327; called by muse, mutect2, varscan2
- HERC2 | c.8425T>G p.W2809G | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55334784; called by muse, varscan2
- HHIP | c.1252A>G p.T418A | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.927); catalogued as COSV56841539; called by muse, mutect2, varscan2
- HIC1 | c.1178G>A p.G393D (on ENST00000322941 / NM_001098202.1; = p.G374D on NM_006497.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.941); catalogued as COSV53970999; called by muse, mutect2, varscan2
- HIPK3 | c.3034G>A p.A1012T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1434156008, COSV57563773; called by muse, mutect2, varscan2
- HIVEP3 | c.5933G>A p.R1978H | Missense Mutation (SNP) | VAF 59/87 reads (68%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as rs144265546; called by muse, mutect2, varscan2
- HK1 | c.592-2A>G p.X198_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as COSV53861524; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-3del | Splice Region (DEL) | VAF 4/24 reads (17%) | catalogued as rs759915055; called by pindel, varscan2
- HOOK2 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs754972063, COSV53402936; called by muse, mutect2, varscan2
- HOXA4 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200302499; called by muse, mutect2, varscan2
- HOXC12 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.649); catalogued as COSV54535366; called by muse, mutect2, varscan2
- HPCAL4 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344262179, COSV65716468; called by muse, mutect2, varscan2
- HRC | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV53257459; called by muse, mutect2, varscan2
- HS3ST6 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV53535705; called by muse, mutect2, varscan2
- HUWE1 | c.10828C>T p.R3610W | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV53354347; called by muse, mutect2, varscan2
- HYAL1 | c.127T>C p.C43R | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56498616; called by muse, mutect2, varscan2
- HYDIN | c.13712A>G p.H4571R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1460036672, COSV66640274; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | catalogued as rs747841314; called by mutect2, varscan2
- IDH1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs779481497, COSV61631102; called by muse, mutect2, varscan2
- IFFO1 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763226796, COSV60738403; called by muse, mutect2, varscan2
- IFIT1 | c.1007del p.K336Sfs*9 | Frame Shift Del (DEL) | VAF 34/96 reads (35%) | catalogued as rs1202143274; called by mutect2, pindel, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 104/160 reads (65%) | catalogued as rs760021495; called by mutect2, varscan2
- IL37 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs767519952, COSV54491581; called by muse, mutect2, varscan2
- IL3RA | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.63); catalogued as rs778345582, COSV58431168; called by muse, mutect2, varscan2
- ILVBL | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201871852; called by muse, mutect2, varscan2
- INTS13 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs756003510, COSV53903722; called by muse, mutect2, varscan2
- INVS | c.2716_2717del p.E906Tfs*96 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as rs1303311376; called by pindel, varscan2
- IQCH | c.2834A>G p.H945R | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV60056167; called by muse, mutect2, varscan2
- IQSEC2 | c.848G>C p.G283A (on ENST00000642864 / NM_001111125.3; = p.G78A on NM_015075.2) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.015); catalogued as rs1241595562, COSV64726734; ClinVar: uncertain significance; called by muse, mutect2
- ISL2 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV51958572; called by muse, mutect2, varscan2
- ITGA1 | c.1223A>G p.Q408R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV50887247; called by muse, mutect2
- ITIH5 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV53669574; called by muse, mutect2, varscan2
- KBTBD4 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs374193777; called by muse, mutect2, varscan2
- KCNB2 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73049071, COSV73050185; called by muse, mutect2, varscan2
- KCNB2 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73051389; called by muse, varscan2
- KCND2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.909); catalogued as COSV58579127; called by muse, mutect2
- KCNK1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV64035625; called by muse, mutect2, varscan2
- KCNK15 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV65720122; called by muse, mutect2, varscan2
- KCNK9 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1190915418, COSV57284824; called by muse, mutect2, varscan2
- KCNS1 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60260502; called by muse, mutect2, varscan2
- KCNV2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1214477952, COSV66056449; called by muse, mutect2, varscan2
- KDM1B | c.1835C>A p.T612N (on ENST00000449850; = p.T379N on NM_153042.4) | Missense Mutation (SNP) | VAF 81/112 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV52812573; called by muse, mutect2, varscan2
- KDM2A | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV67082909; called by muse, mutect2, varscan2
- KDM3A | c.2011A>G p.N671D | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57223280; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 46/142 reads (32%) | catalogued as rs771545848; called by mutect2, varscan2
- KIAA1328 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.105); catalogued as rs531868906, COSV54458460, COSV54458828, COSV54463000; called by muse, mutect2, varscan2
- KIAA1614 | c.1665del p.V556Sfs*21 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs768029757; called by mutect2, pindel, varscan2
- KIF13B | c.3976G>A p.A1326T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as rs772114436, COSV72954269; called by muse, mutect2, varscan2
- KIF15 | c.3992A>C p.K1331T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV58162700; called by muse, mutect2, varscan2
- KIF1A | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1225233710, COSV57494506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF2C | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs766564343, COSV64763878; called by muse, mutect2, varscan2
- KIZ | c.1283del p.N428Ifs*7 | Frame Shift Del (DEL) | VAF 41/133 reads (31%) | catalogued as rs755731853; called by mutect2, pindel, varscan2
- KLHDC3 | c.692del p.P231Rfs*31 | Frame Shift Del (DEL) | VAF 54/201 reads (27%) | catalogued as rs1314513168; called by mutect2, pindel, varscan2
- KLHL26 | c.1729A>G p.I577V | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs760166828, COSV56318240; called by muse, mutect2, varscan2
- KLHL36 | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV50720552; called by muse, mutect2, varscan2
- KLHL8 | c.1253T>C p.I418T | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV56748593; called by muse, mutect2, varscan2
- KLK8 | c.228dup p.P77Tfs*15 | Frame Shift Ins (INS) | VAF 29/117 reads (25%) | catalogued as rs766996637; called by mutect2, pindel, varscan2
- KLRF1 | c.545T>C p.M182T | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV54381442; called by muse, mutect2, varscan2
- KMT2D | c.15871G>A p.E5291K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936142615, COSV56460833; called by muse, mutect2, varscan2
- KRT33A | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.174); catalogued as rs1337488110, COSV50369752; called by muse, mutect2, varscan2
- KRT39 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV62916897; called by muse, mutect2, varscan2
- KRTAP4-12 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV67458073; called by muse, varscan2
- KTN1 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV68024371; called by muse, mutect2, varscan2
- KYNU | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1265027337, COSV51587085; called by muse, mutect2, varscan2
- LAIR1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs200961101, COSV57306210; called by muse, mutect2, varscan2
- LAMA2 | c.9035A>G p.Y3012C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761837358, COSV70351542; called by muse, mutect2, varscan2
- LAMB2 | c.4274del p.G1425Vfs*27 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as COSV59731620; called by mutect2, pindel, varscan2
- LAMB2 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372230106, COSV59734867; called by muse, mutect2, varscan2
- LAMB3 | c.2027_2029del p.L676del | In Frame Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs1553276516; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- LAMB4 | c.2695T>C p.Y899H | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as rs1463095737, COSV52723936; called by muse, mutect2, varscan2
- LANCL1 | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV52065901; called by muse, mutect2, varscan2
- LANCL2 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1456603541, COSV54647503; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDLRAD4 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); catalogued as COSV63340014; called by muse, mutect2, varscan2
- LEP | c.398del p.G133Vfs*15 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs771139087; called by mutect2, pindel, varscan2
- LETMD1 | c.115del p.A39Pfs*15 | Frame Shift Del (DEL) | VAF 50/106 reads (47%) | catalogued as rs1566076595; called by mutect2, varscan2
- LGI3 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); catalogued as rs748894925, COSV60443175; called by muse, mutect2, varscan2
- LGR6 | c.2730del p.R911Gfs*8 (on ENST00000367278 / NM_001017403.1; = p.R859Gfs*8 on NM_021636.3) | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | catalogued as COSV55163759; called by mutect2, pindel, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 44/154 reads (29%) | catalogued as rs748571616; called by mutect2, varscan2
- LIMS2 | c.634G>A p.A212T (on ENST00000355119 / NM_001161403.3; = p.A236T on NM_017980.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs762554883, COSV55755307; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMBR1L | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57201311; called by muse, mutect2, varscan2
- LMTK3 | c.2638del p.A880Rfs*24 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as rs35275345; called by mutect2, varscan2
- LONP2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs776336728, COSV53523959; called by muse, mutect2, varscan2
- LOXL4 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV53257843; called by muse, mutect2, varscan2
- LPIN1 | c.1574C>A p.A525E | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56767663; called by muse, mutect2, varscan2
- LRRC3 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs755355466, COSV52399666; called by muse, mutect2, varscan2
- LRRC73 | c.852_853del p.G285Qfs*28 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as rs766285284; called by pindel, varscan2
- LUZP2 | c.525G>A p.A175= | Splice Region (SNP) | VAF 21/52 reads (40%) | catalogued as rs148359334; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs752439249; called by mutect2, varscan2
- MAD1L1 | c.1594C>G p.Q532E | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56239972; called by muse, mutect2, varscan2
- MAF1 | c.446A>C p.Q149P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV59363568; called by muse, mutect2, varscan2
- MAGEB4 | c.178del p.Q60Rfs*50 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as COSV64396770; called by mutect2, pindel, varscan2
- MANEA | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV62589246; called by muse, mutect2
- MAP10 | c.1682T>C p.I561T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs961906974, COSV69364174; called by muse, mutect2
- MAP2K1 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61072096; called by muse, mutect2, varscan2
- MAP2K7 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607853; called by muse, mutect2, varscan2
- MAP2K7 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV67608956; called by muse, mutect2, varscan2
- MAP4K4 | c.771del p.K257Nfs*10 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as rs774203808; called by mutect2, varscan2
- MARCHF2 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs992957811, COSV53104504; called by muse, mutect2, varscan2
- MARCHF7 | c.886del p.S296Hfs*9 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | catalogued as rs1383130845; called by mutect2, varscan2
- MAX | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV52418152; called by muse, mutect2, varscan2
- MBD4 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs757487617, COSV51445133, COSV99959018; called by muse, mutect2, varscan2
- MCPH1 | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV60916074; called by muse, mutect2, varscan2
- MED12L | c.5670_5672dup p.Q1892dup | In Frame Ins (INS) | VAF 28/88 reads (32%) | catalogued as rs781751830; called by mutect2, varscan2
- MEGF8 | c.2474A>G p.D825G (on ENST00000251268 / NM_001271938.2; = p.D758G on NM_001410.3) | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV52092397; called by muse, mutect2, varscan2
- MGST3 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV63321409; called by muse, mutect2, varscan2
- MIS18BP1 | c.1139dup p.N380Kfs*12 | Frame Shift Ins (INS) | VAF 27/75 reads (36%) | catalogued as rs751180035; called by mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | catalogued as rs749903408; called by mutect2, varscan2
- MMP11 | c.483-1G>T p.X161_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV53157128; called by muse, mutect2, varscan2
- MNS1 | c.846_848del p.E282del | In Frame Del (DEL) | VAF 36/124 reads (29%) | catalogued as rs772432216; called by pindel, varscan2
- MOS | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61336532; called by muse, mutect2, varscan2
- MPP3 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.285); catalogued as rs765597486, COSV68198768; called by muse, mutect2, varscan2
- MREG | c.405T>G p.D135E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV54374827; called by muse, mutect2, varscan2
- MRPL58 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV56901496; called by muse, mutect2, varscan2
- MSMO1 | c.193T>C p.F65L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54970602; called by muse, mutect2, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs759847587; called by mutect2, varscan2
- MTHFS | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1331303414, COSV51914574; called by muse, mutect2, varscan2
- MUC16 | c.7445A>C p.D2482A | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV67455093, COSV67478421; called by muse, mutect2, varscan2
- MX2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0.227); catalogued as rs745448850, COSV58096513; called by muse, mutect2, varscan2
- MYCBP2 | c.9008A>G p.H3003R (on ENST00000357337; = p.H3041R on NM_015057.5) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV62028375; called by muse, mutect2, varscan2
- MYH11 | c.3395C>T p.A1132V | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV55560450; called by muse, mutect2, varscan2
- MYH6 | c.5102G>A p.R1701Q | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762103586, COSV62452468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH9 | c.5671G>A p.A1891T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs748946434, COSV53383305; ClinVar: uncertain significance; called by muse, mutect2
- MYO16 | c.2525T>C p.F842S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV51777480, COSV51804594; called by muse, varscan2
- MYO19 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as rs1409270197; called by mutect2, varscan2
- N6AMT1 | c.418G>C p.A140P | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV58135078; called by muse, mutect2, varscan2
- NBAS | c.4001G>A p.R1334H | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140188229; called by muse, varscan2
- NBEA | c.7537C>T p.R2513C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs868332409, COSV59800978; called by muse, mutect2, varscan2
- NCAM2 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.048); catalogued as COSV53087590; called by muse, mutect2, varscan2
- NDOR1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as COSV61288922; called by muse, mutect2, varscan2
- NDUFB3 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs767171840, COSV52987805; called by muse, mutect2, varscan2
- NEFM | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1284300446, COSV55333281; called by muse, mutect2, varscan2
- NEK8 | c.1924C>T p.R642* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs763288569, COSV52046645; called by muse, mutect2, varscan2
- NETO1 | c.408A>T p.K136N | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55008838; called by muse, mutect2, varscan2
- NEXMIF | c.2986A>G p.M996V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779441513, COSV50051408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NID1 | c.1236C>A p.C412* | Nonsense Mutation (SNP) | VAF 41/108 reads (38%) | catalogued as COSV51624155; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as COSV53499514; called by mutect2, pindel, varscan2
- NKRF | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV58661439; called by muse, mutect2, varscan2
- NLGN1 | c.2383C>T p.H795Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as rs765131109, CM124617, COSV64340052; called by muse, mutect2, varscan2
- NLGN2 | c.1808A>T p.E603V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV57210951; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NLRC3 | c.2810C>T p.A937V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as rs549794584, COSV57091280; called by muse, mutect2, varscan2
- NLRP7 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs778846440, COSV60173062; called by muse, mutect2, varscan2
- NLRX1 | c.2588C>A p.P863H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52704888, COSV52706455; called by muse, mutect2, varscan2
- NONO | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV52138822; called by muse, mutect2, varscan2
- NOS2 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV58225749; called by muse, mutect2, varscan2
- NPBWR1 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs747670302, COSV58696912; called by muse, mutect2
- NRG1 | c.848G>A p.R283Q (on ENST00000405005 / NM_013964.5; = p.R288Q on NM_013956.5) | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as rs145033301, COSV99829962; called by muse, mutect2, varscan2
- NRK | c.3661A>G p.N1221D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54601096; called by muse, mutect2, varscan2
- NRP1 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs554872876, COSV55171299; called by muse, mutect2, varscan2
- NRXN3 | c.2764G>A p.E922K (on ENST00000335750 / NM_001330195.2; = p.E549K on NM_004796.6) | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59719470; called by muse, mutect2, varscan2
- NSD2 | c.3892C>A p.L1298I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV56393273; called by muse, varscan2
- NSRP1 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs760235374, COSV99898262; called by muse, mutect2, varscan2
- NUP188 | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1262892620, COSV65363367; called by muse, mutect2, varscan2
- NYAP1 | c.1154del p.P385Hfs*46 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV55719186; called by mutect2, pindel, varscan2
- OBSCN | c.15031G>T p.A5011S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV52796082; called by muse, mutect2, varscan2
- OBSL1 | c.4894G>A p.V1632M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as rs540208891, COSV54707246, COSV54707882; called by muse, mutect2, varscan2
- OBSL1 | c.2668G>A p.V890I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); catalogued as rs932220238, COSV54707888; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | catalogued as CD000269; called by mutect2, varscan2
- ODAPH | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV100290243, COSV61141403; called by muse, mutect2, varscan2
- ODR4 | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.269); catalogued as rs1196816913, COSV55217662; called by muse, mutect2, varscan2
- OLIG2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV60972362; called by muse, mutect2
- OR2M7 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 133/358 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV100522541, COSV58739725; called by muse, mutect2, varscan2
- OR52D1 | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV59487905; called by muse, mutect2, varscan2
- OR8I2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV56168936; called by muse, mutect2, varscan2
- OTUD6B | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53443427; called by muse, mutect2, varscan2
- OXR1 | c.309T>C p.V103= (on ENST00000442977 / NM_001198532.1; = p.V102= on NM_018002.3) | Splice Region (SNP) | VAF 33/103 reads (32%) | catalogued as COSV56332577; called by muse, mutect2, varscan2
- P2RY2 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 9/104 reads (9%) | catalogued as COSV60775306; called by muse, mutect2
- PAK5 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958970085, COSV100781207, COSV62032194; called by muse, mutect2, varscan2
- PAN3 | c.2341T>A p.F781I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV56705065; called by muse, mutect2, varscan2
- PANX1 | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV57134353; called by muse, mutect2, varscan2
- PARP1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV64691366; called by muse, mutect2, varscan2
- PARP2 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV51640558; called by muse, mutect2, varscan2
- PCBP2 | c.524del p.P175Rfs*4 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as rs776329515; called by mutect2, pindel, varscan2
- PCCA | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301904623, CM992385, COSV66194828; called by muse, mutect2, varscan2
- PCDH19 | c.2372G>A p.R791Q (on ENST00000373034 / NM_001184880.2; = p.R744Q on NM_020766.3) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.17); catalogued as rs886042264, COSV55266763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH9 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60568080; called by muse, mutect2, varscan2
- PCDHA12 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56515355; called by muse, mutect2, varscan2
- PCDHA2 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV65368832; called by muse, mutect2, varscan2
- PCDHA3 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV63543574, COSV99061555; called by muse, mutect2, varscan2
- PCDHA6 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV65352427; called by muse, mutect2, varscan2
- PCDHA7 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.109); catalogued as rs147416989, COSV65345591; called by muse, mutect2, varscan2
- PCDHB16 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs192987001, COSV53360069, COSV53374667; called by muse, mutect2, varscan2
- PCDHB16 | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.778); catalogued as rs1554282411, COSV53366150; called by muse, mutect2
- PCDHGA12 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.047); catalogued as rs769224543, COSV52745549; called by muse, mutect2, varscan2
- PCDHGA4 | c.971A>C p.Q324P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.786); catalogued as rs779701115, COSV53983726, COSV53993962; called by muse, mutect2, varscan2
- PCDHGA4 | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV53983749; called by muse, mutect2, varscan2
- PCDHGA5 | c.2393A>C p.D798A | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV53983802, COSV99544792; called by muse, mutect2, varscan2
- PCDHGB1 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.089); catalogued as COSV53902887, COSV53959411; called by muse, mutect2, varscan2
- PCDHGB2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53962602; called by muse, mutect2, varscan2
- PCDHGB5 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1400790755, COSV53910476; called by muse, mutect2, varscan2
- PCDHGC3 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV52758205; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 87/245 reads (36%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNX1 | c.5471C>T p.A1824V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53097442; called by muse, mutect2, varscan2
- PCSK4 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369866068, COSV99278484; called by muse, mutect2, varscan2
- PDK3 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1211281591, COSV64793838; called by muse, mutect2, varscan2
- PEAK1 | c.4601A>G p.Q1534R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV56939323; called by muse, mutect2, varscan2
- PELI1 | c.105_107del p.R37del | In Frame Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs758525254; called by mutect2, pindel, varscan2
- PES1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as rs1309488100, COSV58829171; called by muse, mutect2, varscan2
- PEX1 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as COSV50404421; called by muse, mutect2, varscan2
- PHF12 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs758095952, COSV52018668, COSV99255433; called by muse, mutect2, varscan2
- PHF2 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs530932207, COSV63682211; called by muse, mutect2, varscan2
- PHF8 | c.1324G>T p.A442S (on ENST00000357988 / NM_001184896.1; = p.A406S on NM_015107.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57684341; called by muse, mutect2, varscan2
- PHKA1 | c.2539C>G p.L847V | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV59808148; called by muse, mutect2, varscan2
- PIDD1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs756216117, COSV61703946; called by muse, mutect2, varscan2
- PIF1 | c.600G>T p.L200F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.295); catalogued as COSV51423198; called by muse, mutect2, varscan2
- PIK3AP1 | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV59534418; called by muse, mutect2, varscan2
- PIPOX | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs142705261; called by muse, mutect2, varscan2
- PIWIL2 | c.2393del p.K798Sfs*5 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as COSV63249731; called by mutect2, pindel, varscan2
- PKN2 | c.2671-1G>A p.X891_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV65143638; called by muse, mutect2, varscan2
- PLA2G2A | c.118A>G p.S40G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); catalogued as COSV64287431; called by muse, mutect2, varscan2
- PLAG1 | c.551del p.K184Sfs*45 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as rs141930943; called by mutect2, varscan2
- PLCD1 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs372093444; called by muse, mutect2, varscan2
- PLD2 | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs138719274; called by muse, mutect2, varscan2
- PLEC | c.13675G>A p.A4559T (on ENST00000322810 / NM_201380.4; = p.A4449T on NM_000445.5) | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs782099999, COSV59659079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.3587C>A p.A1196E (on ENST00000322810 / NM_201380.4; = p.A1086E on NM_000445.5) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs529986115, CM157196, COSV59659140; called by muse, mutect2, varscan2
- PLEC | c.753+2T>A p.X251_splice (on ENST00000322810 / NM_201380.4; = p.X141_splice on NM_000445.5) | Splice Site (SNP) | VAF 15/66 reads (23%) | catalogued as COSV59659168; called by muse, mutect2, varscan2
- PLEKHB2 | c.100T>C p.Y34H | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52176835; called by muse, varscan2
- PLEKHH1 | c.2998C>A p.P1000T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61285393; called by muse, mutect2, varscan2
- PLIN4 | c.1780del p.A594Qfs*2 (on ENST00000301286; = p.A609Qfs*2 on NM_001367868.2) | Frame Shift Del (DEL) | VAF 97/329 reads (29%) | catalogued as rs751480984; called by mutect2, pindel, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as rs772701630; called by mutect2, varscan2
- PLOD3 | c.876del p.Q293Sfs*65 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs746342377, COSV56183473; called by pindel, varscan2
- PLP1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.761); catalogued as rs132630295, CM078425, CM1312266, COSV58277298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLPPR5 | c.195dup p.V66Rfs*33 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | catalogued as rs1481324917; called by mutect2, pindel, varscan2
- PLXNA1 | c.2639C>T p.T880M | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs770145599, COSV52529337; called by muse, mutect2, varscan2
- PLXNA4 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58141798; called by muse, mutect2, varscan2
- PLXNB3 | c.4108C>G p.L1370V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62799351; called by muse, mutect2, varscan2
- PMPCA | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs368032224; called by muse, mutect2, varscan2
- POGZ | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV55038588; called by muse, mutect2, varscan2
- POU3F3 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV63722088; called by muse, mutect2, varscan2
- POU5F2 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 15/21 reads (71%) | catalogued as rs1266630516, COSV67939807; called by muse, mutect2, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | catalogued as rs775130624; called by mutect2, pindel, varscan2
- PPP2R5B | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs141499148; called by muse, mutect2, varscan2
- PPP2R5C | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV58273643; called by muse, mutect2, varscan2
- PRKCG | c.1093-2A>G p.X365_splice | Splice Site (SNP) | VAF 16/43 reads (37%) | catalogued as COSV54730078, COSV99669560; called by muse, mutect2, varscan2
- PRMT8 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54212047; called by muse, mutect2, varscan2
- PROSER3 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56554100, COSV99994643; called by muse, mutect2, varscan2
- PRPSAP1 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs774132458, COSV61211836; called by muse, mutect2, varscan2
- PRRC2B | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs917198420, COSV61939677; called by muse, mutect2, varscan2
- PRRC2B | c.3290G>A p.R1097H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs369418138; called by muse, mutect2
- PRUNE2 | c.7861A>G p.R2621G | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs553375575, COSV65043855; called by muse, mutect2, varscan2
- PSG11 | c.6del p.L4Sfs*22 | Frame Shift Del (DEL) | VAF 25/145 reads (17%) | catalogued as COSV60453665; called by mutect2, pindel, varscan2
- PSMB5 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs369529779; called by muse, mutect2, varscan2
- PXDNL | c.1799T>C p.I600T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV62492858; called by muse, mutect2, varscan2
- PYGO1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs147959519; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RAC3 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs760585885, COSV60711965; called by muse, mutect2, varscan2
- RASGRF1 | c.2804del p.P935Qfs*11 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs1567482049; called by mutect2, pindel, varscan2
- RBM42 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs371819218; called by muse, mutect2
- RBM48 | c.402del p.K134Nfs*9 | Frame Shift Del (DEL) | VAF 31/113 reads (27%) | catalogued as rs754768719; called by mutect2, pindel, varscan2
- RBM48 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs777152272, COSV56003127; called by muse, mutect2, varscan2
- RCVRN | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56841903; called by muse, mutect2, varscan2
- REXO1 | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1172715654, COSV50082079; called by muse, mutect2, varscan2
- RFC1 | c.1903T>A p.F635I (on ENST00000381897 / NM_001363496.2; = p.F634I on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV62900262; called by muse, mutect2, varscan2
- RGS6 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs943814526, COSV59564700, COSV59566926; called by muse, mutect2, varscan2
- RHBDF1 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs754018001, COSV51956637; called by muse, mutect2, varscan2
- RIC1 | c.2938C>T p.R980* | Nonsense Mutation (SNP) | VAF 15/172 reads (9%) | catalogued as COSV52611985; called by muse, mutect2
- RIF1 | c.5514T>G p.I1838M | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as COSV54620007; called by muse, mutect2, varscan2
- RIF1 | c.6718G>A p.V2240I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs1224717115, COSV54620019; called by muse, mutect2, varscan2
- RIMS1 | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs1481837668, COSV53467600; called by muse, varscan2
- RIMS2 | c.3134G>A p.R1045Q (on ENST00000666250 / NM_001348490.2; = p.R853Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as rs776394480, COSV51665828; called by muse, mutect2, varscan2
- RIPOR1 | c.3215G>A p.R1072Q (on ENST00000379312 / NM_001193522.2; = p.R1068Q on NM_024519.4) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs765457861, COSV50234978; called by muse, varscan2
- RNF128 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55252606; called by muse, varscan2
- RNF128 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55252620; called by muse, varscan2
- RNF144A | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs151171616; called by muse, mutect2
- RNF43 | c.931del p.L311Sfs*108 | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | catalogued as COSV68457393; called by mutect2, varscan2
- RPRD1A | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59822603; called by muse, mutect2, varscan2
- RPTOR | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs745951041, COSV60806410, COSV60812724; called by muse, mutect2, varscan2
- RRAGD | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 125/315 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63269664; called by muse, mutect2, varscan2
- RSPH10B2 | c.2566G>A p.V856M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as rs751494187, COSV99786096; called by mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs747510098; called by mutect2, varscan2
- RTN4 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1305864629, COSV58270214; called by muse, mutect2, varscan2
- RTP2 | c.337A>T p.N113Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64079229; called by muse, mutect2, varscan2
- RUBCN | c.2245T>G p.C749G | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as COSV56369577; called by muse, mutect2, varscan2
- RYR2 | c.11674T>C p.Y3892H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63697637; called by muse, mutect2, varscan2
- S1PR1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs140298731; called by muse, mutect2, varscan2
- SAMHD1 | c.1682del p.K561Rfs*35 (on ENST00000262878 / NM_001363729.2; = p.K596Rfs*35 on NM_015474.4) | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | catalogued as rs1215993198; called by mutect2, pindel, varscan2
- SATL1 | c.499C>T p.R167* (on ENST00000395409; = p.R354* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as rs374764586, COSV60575818; called by muse, mutect2, varscan2
- SBNO2 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs770824881, COSV62321815; called by muse, varscan2
- SCN1A | c.5062G>T p.G1688W (on ENST00000303395 / NM_001202435.3; = p.G1677W on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM113359, COSV57677509; called by muse, mutect2, varscan2
- SCN1A | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as rs184524479, COSV57677537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.5233C>T p.R1745C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs749841448, COSV71127756; called by muse, mutect2, varscan2
- SCN4A | c.4361G>A p.R1454Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs374074988; called by muse, mutect2
- SCN9A | c.5964del p.K1988Nfs*20 (on ENST00000303354; = p.K1977Nfs*20 on NM_002977.3) | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs1558938258; called by mutect2, pindel, varscan2
- SCYL3 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200012098, COSV63045582; called by muse, mutect2, varscan2
- SDK1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs547185174, COSV67373532; called by muse, mutect2, varscan2
- SEC14L2 | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV57241807; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs768388757; called by mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 50/80 reads (63%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA4D | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs759275072, COSV59391180; called by muse, mutect2, varscan2
- SERPINA6 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs778913169, COSV58586179; called by muse, mutect2, varscan2
- SERPINE3 | c.808del p.L270* | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs753981280; called by mutect2, pindel
- SETD9 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs372166694; called by muse, mutect2, varscan2
- SETDB2 | c.2152del p.I718Yfs*11 | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | catalogued as rs775302281, COSV57902985; called by mutect2, varscan2
- SGK1 | c.1064_1066del p.F355del | In Frame Del (DEL) | VAF 32/136 reads (24%) | catalogued as rs1562235638; called by pindel, varscan2
- SGSM1 | c.3043del p.H1015Tfs*12 (on ENST00000400359 / NM_001039948.4; = p.H954Tfs*12 on NM_133454.3) | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs1271954029; called by mutect2, pindel, varscan2
- SH3KBP1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs1358291133, COSV65643034; called by muse, mutect2, varscan2
- SHISA3 | c.458C>A p.T153N | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.239); catalogued as COSV59980244; called by muse, mutect2, varscan2
- SHROOM3 | c.3733G>A p.A1245T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1367251404, COSV56033933; called by muse, mutect2, varscan2
- SHROOM4 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192380439, COSV56792766; called by muse, mutect2, varscan2
- SHROOM4 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV56792778; called by muse, mutect2, varscan2
- SIRPA | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs143335460, COSV100605123; called by muse, mutect2, varscan2
- SLC10A6 | c.326del p.G109Afs*21 | Frame Shift Del (DEL) | VAF 39/127 reads (31%) | catalogued as rs753933531, COSV56721805; called by mutect2, pindel, varscan2
- SLC16A6 | c.294del p.L99Yfs*39 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs782184620; called by mutect2, pindel, varscan2
- SLC19A2 | c.648_650del p.F217del | In Frame Del (DEL) | VAF 24/67 reads (36%) | catalogued as rs765261078; called by pindel, varscan2
- SLC22A23 | c.1026G>A p.W342* | Nonsense Mutation (SNP) | VAF 22/32 reads (69%) | catalogued as rs1299630019, COSV66674265; called by muse, mutect2, varscan2
- SLC22A3 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV51714849; called by muse, mutect2, varscan2
- SLC24A3 | c.1429A>G p.M477V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV60124746; called by muse, mutect2, varscan2
- SLC28A2 | c.80T>C p.M27T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1018877691, COSV61664624; called by muse, mutect2, varscan2
- SLC2A12 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs372770684; called by muse, mutect2, varscan2
- SLC35D1 | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV52432163; called by muse, mutect2, varscan2
- SLC35E4 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as COSV55898668; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC45A3 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as rs571524594, COSV65655155; called by muse, mutect2, varscan2
- SLC4A1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs760404726, COSV52260579; called by muse, mutect2, varscan2
- SLC7A13 | c.73A>G p.N25D | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.381); catalogued as rs754475807, COSV52535763; called by muse, mutect2, varscan2
- SLC8A2 | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.767); catalogued as COSV52641058; called by muse, mutect2
- SLC9A7 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60381745; called by muse, mutect2, varscan2
- SLIT3 | c.4326C>G p.H1442Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV60620105; called by muse, mutect2
- SLITRK2 | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 58/179 reads (32%) | catalogued as rs1556945144, COSV59427015; called by muse, mutect2, varscan2
- SLTM | c.1460del p.N487Ifs*35 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs762322084; called by mutect2, varscan2
- SMARCA4 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60786870; called by muse, mutect2, varscan2
- SMARCA4 | c.3046G>A p.V1016M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs770969438, COSV60795946; called by muse, mutect2, varscan2
- SMC1B | c.2003A>C p.E668A | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62531372; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SMC3 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV62421109; called by muse, mutect2, varscan2
- SMC5 | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as rs374607515; called by muse, mutect2, varscan2
- SMG6 | c.2442G>T p.K814N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53971012; called by muse, mutect2, varscan2
- SND1 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs889429536; called by muse, mutect2
- SNW1 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1349964407, COSV53174565, COSV99473147; called by muse, mutect2, varscan2
- SNX18 | c.1277G>A p.S426N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as COSV57990688; called by muse, mutect2
- SNX30 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.266); catalogued as rs759012933, COSV65292868; called by muse, mutect2, varscan2
- SOBP | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.429); catalogued as rs1011123709, COSV58000341; called by muse, mutect2, varscan2
- SOCS5 | c.1308C>G p.N436K | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.344); catalogued as COSV60605600; called by muse, mutect2, varscan2
- SOGA3 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV64107497; called by muse, mutect2, varscan2
- SORCS3 | c.1237T>C p.Y413H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.302); catalogued as COSV63816499; called by muse, mutect2, varscan2
- SORL1 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs752341524, COSV52757675; called by muse, varscan2
- SP140 | c.2015dup p.R673Efs*9 | Frame Shift Ins (INS) | VAF 13/37 reads (35%) | catalogued as rs746109620; called by mutect2, varscan2
- SP6 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as rs780881543, COSV100646969, COSV60618457; called by muse, mutect2, varscan2
- SPATA17 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as rs1204987538, COSV65119175, COSV65119823; called by muse, mutect2, varscan2
- SPATA25 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.425); catalogued as COSV51943349; called by muse, mutect2, varscan2
- SPECC1L | c.2527A>G p.T843A | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV58659772; called by muse, mutect2, varscan2
- SPEM2 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV61604249; called by muse, mutect2, varscan2
- SPTA1 | c.4849C>T p.R1617W | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs745646823, COSV63756375, COSV63758949; called by muse, mutect2, varscan2
- SPTY2D1 | c.96dup p.D33Rfs*5 | Frame Shift Ins (INS) | VAF 33/98 reads (34%) | catalogued as rs1263882321; called by mutect2, varscan2
- SRRM1 | c.1139G>A p.S380N | Missense Mutation (SNP) | VAF 81/125 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV60478860; called by muse, mutect2, varscan2
- SSH3 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs888479896, COSV57385617; called by muse, mutect2, varscan2
- SSTR2 | c.763A>G p.T255A | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59535683; called by muse, mutect2, varscan2
- ST14 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1314976809, COSV53832316; called by muse, mutect2, varscan2
- ST3GAL3 | c.1060G>A p.V354I (on ENST00000361392 / NM_174964.4; = p.V339I on NM_006279.5) | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs767586606, COSV53516516; called by muse, mutect2, varscan2
- STMN4 | c.496C>T p.R166W (on ENST00000265770 / NM_001283054.2; = p.R193W on NM_030795.4) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs764508091, COSV56108272; called by muse, mutect2, varscan2
- STRN | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55749708; called by muse, mutect2, varscan2
- STXBP2 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs141717050, CM1311992, COSV99656820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUCNR1 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62912000, COSV62912532; called by muse, mutect2, varscan2
- SUPT6H | c.1784A>G p.Q595R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV58929238; called by muse, mutect2
- SUSD2 | c.2444C>T p.T815M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1324843581, COSV64204623; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs770033147; called by mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs570102997; called by mutect2, varscan2
- SYK | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV65328501; called by muse, mutect2, varscan2
- SYNE1 | c.23863C>T p.H7955Y (on ENST00000367255 / NM_182961.4; = p.H7884Y on NM_033071.3) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54996060; called by muse, mutect2
- SYNE2 | c.17641G>A p.V5881M | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as rs1441754897, COSV59958112; called by muse, mutect2, varscan2
- TBC1D9B | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.982); catalogued as rs200585012, COSV62282868; called by muse, mutect2, varscan2
- TCEAL5 | c.188A>C p.E63A | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV65503377; called by muse, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 36/99 reads (36%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF20 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV59493801; called by muse, mutect2, varscan2
- TCHH | c.5297G>A p.R1766H | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV64276176; called by muse, mutect2, varscan2
- TDRD5 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.521); catalogued as rs199784694; called by muse, mutect2, varscan2
- TDRD7 | c.1852_1854del p.V618del | In Frame Del (DEL) | VAF 23/134 reads (17%) | catalogued as rs750207077; called by pindel, varscan2
- TEAD1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57567252; called by muse, mutect2
- TEKT4 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.243); catalogued as rs532642441, COSV54626359; called by muse, mutect2, varscan2
- TENM1 | c.7732C>A p.L2578I | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.184); catalogued as COSV64437021; called by muse, mutect2
- TENM3 | c.6498C>A p.N2166K | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV69313294; called by muse, mutect2, varscan2
- TEPP | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); catalogued as COSV52043757; called by muse, mutect2
- THRB | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); catalogued as COSV62839302; called by muse, mutect2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TM2D2 | c.122A>C p.E41A | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as COSV65961132; called by muse, mutect2, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 48/145 reads (33%) | catalogued as rs760930120; called by mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 30/54 reads (56%) | catalogued as rs754390908; called by mutect2, varscan2
- TMCO3 | c.1906G>A p.V636I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs550159257, COSV64806787; called by muse, mutect2, varscan2
- TMEM132E | c.1124T>A p.V375D (on ENST00000321639; = p.V465D on NM_001304438.2) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58698750; called by muse, mutect2, varscan2
- TMEM204 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54153697; called by muse, mutect2, varscan2
- TMEM87B | c.773del p.L258Wfs*27 | Frame Shift Del (DEL) | VAF 32/126 reads (25%) | catalogued as rs750138307; called by mutect2, pindel, varscan2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 83/145 reads (57%) | catalogued as rs747222326; called by mutect2, pindel, varscan2
- TNR | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as rs376305450; called by muse, mutect2, varscan2
- TNS3 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60794470; called by mutect2, varscan2
- TPBG | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.32); catalogued as COSV63882795; called by muse, mutect2, varscan2
- TPR | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.643); catalogued as COSV66602906; called by muse, mutect2, varscan2
- TRAF1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV65868866; called by muse, mutect2, varscan2
- TRBV5-1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs773023358; called by muse, mutect2, varscan2
- TRPM3 | c.2246G>A p.R749H (on ENST00000357533 / NM_001366142.2; = p.R592H on NM_020952.6) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs1420430451, COSV62589756; called by muse, mutect2, varscan2
- TRPV4 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.15); catalogued as COSV55683477; called by muse, mutect2, varscan2
- TRPV5 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as rs1350410887, COSV54687679; called by muse, mutect2, varscan2
- TSHZ2 | c.906A>C p.K302N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV104413768, COSV61589901; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs201653034, COSV54649808; called by muse, mutect2, varscan2
- TSPOAP1 | c.1237del p.V413* | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as COSV52119364; called by mutect2, pindel, varscan2
- TTF1 | c.1007dup p.K337Efs*9 | Frame Shift Ins (INS) | VAF 45/142 reads (32%) | catalogued as rs772401251; called by mutect2, varscan2
- TTN | c.7129G>T p.V2377F (on ENST00000591111; = p.V2331F on NM_003319.4) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | PolyPhen probably damaging (0.998); catalogued as COSV60181193; called by muse, mutect2, varscan2
- TUBGCP6 | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs369335591; called by muse, mutect2, varscan2
- TULP2 | c.1061G>T p.R354I | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55478985; called by muse, mutect2, varscan2
- U2AF2 | c.486+2T>C p.X162_splice | Splice Site (SNP) | VAF 15/28 reads (54%) | catalogued as COSV58275104; called by muse, mutect2, varscan2
- UBA7 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs1429664935, COSV61092768; called by muse, mutect2, varscan2
- UNC119 | c.610+6C>T | Splice Region (SNP) | VAF 18/70 reads (26%) | catalogued as rs766092142, COSV99971658; called by muse, mutect2, varscan2
- UNC50 | c.533del p.F178Sfs*7 | Frame Shift Del (DEL) | VAF 55/183 reads (30%) | catalogued as rs752307344; called by mutect2, pindel, varscan2
- UNCX | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV60333411; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs767420916; called by mutect2, varscan2
- USB1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1345800871, COSV54622865; called by muse, mutect2, varscan2
- USHBP1 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs750844210, COSV53104784; called by muse, mutect2, varscan2
- USHBP1 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV53104807; called by muse, mutect2, varscan2
- USP2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs113893557; called by muse, varscan2
- USP36 | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs559790137, COSV61752549; called by muse, mutect2, varscan2
- USP9X | c.4792_4794del p.D1598del | In Frame Del (DEL) | VAF 36/105 reads (34%) | catalogued as rs1372901093; called by pindel, varscan2
- UTF1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100444105; called by muse, mutect2
- UTS2R | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1361693078, COSV57452957; called by muse, mutect2
- VARS1 | c.3478G>A p.A1160T | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs371570157, COSV63304891; called by muse, mutect2, varscan2
- VCAN | c.6769G>T p.G2257* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as COSV54110281; called by muse, mutect2, varscan2
- VPS18 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1402733811, COSV55031286; called by muse, mutect2, varscan2
- VRTN | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs755595228, COSV56439706; called by muse, mutect2, varscan2
- VWA1 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as rs774823840, COSV58600211; called by muse, mutect2
- WBP1L | c.392A>T p.Q131L | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV64009403; called by muse, mutect2, varscan2
- WDFY3 | c.4018C>T p.R1340W | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1375406293, COSV55707045; called by muse, mutect2, varscan2
- WDR3 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.041); catalogued as rs751941966, COSV60452577; called by muse, mutect2, varscan2
- WDR47 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 142/356 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63058721; called by muse, mutect2, varscan2
- WFS1 | c.2413C>T p.R805W | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs763107032, COSV56990145; called by muse, mutect2, varscan2
- WNK3 | c.3016C>A p.P1006T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV63614951; called by muse, mutect2, varscan2
- WWC3 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1418681309, COSV66504998; called by muse, mutect2, varscan2
- XYLT2 | c.1584dup p.G529Rfs*17 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | catalogued as rs779864368; called by mutect2, varscan2
- YLPM1 | c.284del p.G95Afs*124 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs773058360; called by mutect2, pindel
- ZADH2 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.025); catalogued as rs200839094, COSV59269161; called by muse, mutect2, varscan2
- ZBTB41 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV66359455; called by muse, mutect2, varscan2
- ZBTB5 | c.1999T>C p.W667R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV57040777; called by muse, mutect2, varscan2
- ZBTB7C | c.394del p.D132Tfs*90 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as COSV59691020; called by mutect2, pindel, varscan2
- ZC3H3 | c.302del p.G101Afs*102 | Frame Shift Del (DEL) | VAF 40/138 reads (29%) | catalogued as rs760469533; called by mutect2, pindel, varscan2
- ZC3H4 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756950439, COSV53410194; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs781677398, COSV57709922; called by mutect2, varscan2
- ZFHX4 | c.7819C>T p.R2607C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309561230, COSV50480018, COSV50538350, COSV99265401; called by muse, mutect2, varscan2
- ZHX2 | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as rs202088448; called by muse, mutect2, varscan2
- ZMYM3 | c.1235G>A p.C412Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58739165; called by muse, mutect2, varscan2
- ZNF14 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59850383; called by muse, mutect2, varscan2
- ZNF184 | c.649A>T p.K217* | Nonsense Mutation (SNP) | VAF 159/222 reads (72%) | catalogued as COSV53004432, COSV53004829; called by muse, mutect2, varscan2
- ZNF236 | c.4229C>T p.T1410M | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs774158132, COSV53483030, COSV53492525; called by muse, mutect2, varscan2
- ZNF280B | c.1577A>T p.D526V | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV64529260; called by muse, mutect2, varscan2
- ZNF320 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs770340803, COSV67088513; called by muse, mutect2, varscan2
- ZNF337 | c.2028G>T p.W676C | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV53322168; called by muse, mutect2, varscan2
- ZNF354B | c.866T>C p.L289S | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV59366767; called by muse, mutect2, varscan2
- ZNF441 | c.436T>C p.C146R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63540302; called by muse, mutect2, varscan2
- ZNF445 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV68539215; called by muse, mutect2, varscan2
- ZNF446 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV52181431; called by muse, mutect2, varscan2
- ZNF474 | c.1094A>G p.*365Wext*37 | Nonstop Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as rs767444157, COSV56946755; called by muse, mutect2, varscan2
- ZNF48 | c.733del p.E245Sfs*47 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as COSV100198003, COSV60783190; called by mutect2, pindel, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF566 | c.927del p.K309Nfs*139 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | catalogued as rs750272831, COSV67573844; called by mutect2, pindel, varscan2
- ZNF574 | c.2615T>C p.V872A | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV55905237; called by muse, mutect2, varscan2
- ZNF596 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1322210432, COSV57654477; called by muse, mutect2, varscan2
- ZNF638 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781350176, COSV52491355; called by muse, mutect2, varscan2
- ZNF665 | c.1235G>A p.R412Q (on ENST00000600412; = p.R477Q on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754940609, COSV67216269; called by muse, mutect2, varscan2
- ZNF665 | c.274C>T p.H92Y (on ENST00000600412; = p.H157Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs769024927, COSV67216280; called by muse, mutect2, varscan2
- ZNF676 | c.200G>T p.R67I (on ENST00000650058; = p.R35I on NM_001001411.3) | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV68093866; called by muse, mutect2
- ZSWIM4 | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs181751370, COSV54323895; called by muse, mutect2, varscan2
- ABCA2 | c.13del p.T5Rfs*77 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- ABCC4 | c.2648del p.L883Wfs*7 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- ACAD11 | c.1608del p.K536Nfs*34 | Frame Shift Del (DEL) | VAF 49/149 reads (33%) | called by mutect2, pindel, varscan2
- AKAP9 | c.4000dup p.T1334Nfs*2 | Frame Shift Ins (INS) | VAF 8/43 reads (19%) | called by mutect2, varscan2
- AKR1E2 | c.935_936del p.K312Rfs*30 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- ANKRD50 | c.2897del p.L966* | Frame Shift Del (DEL) | VAF 35/110 reads (32%) | called by mutect2, pindel, varscan2
- ARID1A | c.5050_5051del p.S1684Hfs*13 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | called by pindel, varscan2
- ASPHD1 | c.336dup p.G113Wfs*29 | Frame Shift Ins (INS) | VAF 27/75 reads (36%) | called by mutect2, pindel, varscan2
- B3GNT5 | c.94del p.W32Gfs*9 | Frame Shift Del (DEL) | VAF 52/142 reads (37%) | called by mutect2, varscan2
- BMP1 | c.2660del p.G887Vfs*70 | Frame Shift Del (DEL) | VAF 43/230 reads (19%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.2395del p.D799Tfs*35 | Frame Shift Del (DEL) | VAF 87/274 reads (32%) | called by mutect2, pindel, varscan2
- CCDC39 | c.384del p.K128Nfs*5 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- CCDC6 | c.268_270del p.E90del | In Frame Del (DEL) | VAF 27/68 reads (40%) | called by pindel, varscan2
423 further variants in this file (128 protein-altering or splice-affecting, 270 silent, 25 other) are not listed here.
